Somatic mutation profile of tumor specimen TCGA-A5-A0GW-01A (aliquot TCGA-A5-A0GW-01A-11W-A062-09) from TCGA case TCGA-A5-A0GW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 46.8 years (17,092 days).
Specimen TCGA-A5-A0GW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38ef9e5a-7e26-4289-9661-1432124e6b9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0GW-10A (Blood Derived Normal), aliquot TCGA-A5-A0GW-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eca83f5e-89ef-4617-b9e9-ff8841f106dc

The open-access MAF lists 445 somatic variants for this specimen: 326 protein-altering or splice-affecting, 110 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 188, Silent 110, Frame Shift Del 98, Frame Shift Ins 13, Nonsense Mutation 11, Splice Region 6, Splice Site 4, In Frame Del 4, Intron 3, 3'UTR 3, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.1813del p.I605Yfs*9 | Frame Shift Del (DEL) | VAF 24/118 reads (20%) | catalogued as rs80359306; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CPAMD8 | c.2352del p.R785Efs*32 (on ENST00000651564; = p.R738Efs*32 on NM_015692.5) | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, pindel
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 30/92 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 22/78 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HEXB | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 63/283 reads (22%) | catalogued as rs121907986, CM940931, COSV54668906; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IGHMBP2 | c.2362C>T p.R788* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs199839840, CM034538; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 33/158 reads (21%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- MTM1 | c.969dup p.V324Sfs*8 | Frame Shift Ins (INS) | VAF 60/293 reads (20%) | catalogued as rs587783865; ClinVar: pathogenic; called by mutect2, varscan2
- NFE2L2 | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 19/84 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67960005, COSV67960666; called by muse, mutect2, varscan2
- PALB2 | c.3143del p.K1048Rfs*27 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | catalogued as rs1555458822, CM118270; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3R1 | c.1354T>A p.Y452N (on ENST00000521381 / NM_181523.3; = p.Y182N on NM_181504.4) | Missense Mutation (SNP) | VAF 35/100 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV57129574, COSV57137992; called by muse, varscan2
- PIK3R1 | c.1384_1386dup p.E462dup (on ENST00000521381 / NM_181523.3; = p.E192dup on NM_181504.4) | In Frame Ins (INS) | VAF 28/95 reads (29%) | hotspot (GDC flag); called by pindel, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 79/314 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RECQL | c.120del p.V41Sfs*2 | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | catalogued as rs745659712, COSV59084411; ClinVar: pathogenic; called by mutect2, varscan2
- STXBP1 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs796053374, CM162502, COSV64815124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.695T>C p.I232T | Missense Mutation (SNP) | VAF 25/114 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs587781589, CM103212, COSV52661257, COSV52760307, COSV52829354; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1508C>T p.A503V (on ENST00000404938 / NM_001163941.2; = p.A58V on NM_178559.6) | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750998883, COSV51706481; called by muse, mutect2, varscan2
- ABCC10 | c.1426G>A p.G476R (on ENST00000372530 / NM_001198934.2; = p.G433R on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs755874920, COSV55093379; called by muse, mutect2, varscan2
- ADAMTS4 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.695); catalogued as rs147572611; called by muse, mutect2, varscan2
- ADCY5 | c.1691G>A p.G564E | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59203549; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 46/196 reads (23%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRG3 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs141398818; called by muse, mutect2, varscan2
- AFF3 | c.2045A>G p.E682G | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV57870596; called by muse, mutect2, varscan2
- AHNAK | c.12593T>C p.M4198T | Missense Mutation (SNP) | VAF 100/420 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV57227810; called by muse, mutect2, varscan2
- AHNAK | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs369654662; called by muse, mutect2, varscan2
- AIFM1 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.196); catalogued as COSV54857434; called by muse, mutect2, varscan2
- AIM2 | c.959del p.N320Mfs*7 | Frame Shift Del (DEL) | VAF 84/353 reads (24%) | catalogued as rs752653022, COSV63698332; called by mutect2, pindel, varscan2
- AL035460.1 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.851); catalogued as COSV63028594; called by muse, mutect2, varscan2
- ANKRD22 | c.28T>C p.C10R | Missense Mutation (SNP) | VAF 54/362 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64237482; called by muse, mutect2, varscan2
- ANKRD42 | c.1150G>T p.D384Y | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV52617955; called by muse, mutect2, varscan2
- AP1B1 | c.1768C>T p.H590Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as COSV58022975; called by muse, mutect2
- ARHGAP6 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 74/257 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.488); catalogued as COSV57302325; called by muse, mutect2, varscan2
- ARNT | c.2101G>T p.G701* | Nonsense Mutation (SNP) | VAF 31/159 reads (19%) | catalogued as COSV62232095; called by muse, mutect2, varscan2
- ASAP1 | c.1157A>G p.D386G | Missense Mutation (SNP) | VAF 49/295 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63053797; called by muse, mutect2, varscan2
- ASH1L | c.7582C>T p.R2528C (on ENST00000368346 / NM_001366177.2; = p.R2523C on NM_018489.3) | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as rs1376913986, COSV64208707; called by muse, mutect2, varscan2
- ASIC4 | c.998G>A p.C333Y | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61733194; called by muse, mutect2, varscan2
- ASXL3 | c.4696C>T p.P1566S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV52457898; called by muse, mutect2, varscan2
- ATP2A1 | c.1712del p.P571Rfs*21 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs772363145; called by mutect2, pindel
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 46/191 reads (24%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- ATXN3L | c.293A>G p.E98G | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV66076188; called by muse, mutect2
- AZIN2 | c.333C>A p.C111* | Nonsense Mutation (SNP) | VAF 31/118 reads (26%) | catalogued as COSV53858146, COSV53860398; called by muse, mutect2, varscan2
- BACH1 | c.432del p.K144Nfs*22 | Frame Shift Del (DEL) | VAF 56/258 reads (22%) | catalogued as rs748639705; called by mutect2, pindel, varscan2
- BIRC2 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.568); catalogued as COSV57162921; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 59/198 reads (30%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BOC | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.32); catalogued as rs142636875; called by muse, mutect2, varscan2
- BRCA2 | c.9995C>A p.S3332Y | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs876658246, COSV66337711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C15orf39 | c.580del p.V194Cfs*132 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs749135337, COSV100641311; called by mutect2, pindel, varscan2
- C19orf47 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.79); catalogued as COSV63510932; called by muse, mutect2, varscan2
- C1orf94 | c.1664G>A p.R555Q (on ENST00000488417 / NM_001134734.2; = p.R365Q on NM_032884.5) | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as rs114160812, COSV64915494; called by muse, mutect2, varscan2
- CACYBP | c.432del p.V145Sfs*22 | Frame Shift Del (DEL) | VAF 42/184 reads (23%) | catalogued as rs1161545619; called by mutect2, varscan2
- CAMSAP2 | c.402T>C p.S134= | Splice Region (SNP) | VAF 56/261 reads (21%) | catalogued as rs1361707692, COSV52676399; called by muse, mutect2, varscan2
- CCDC191 | c.2398G>A p.A800T | Missense Mutation (SNP) | VAF 118/436 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.16); catalogued as COSV55675715; called by muse, mutect2, varscan2
- CCDC40 | c.661G>C p.V221L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53903999; called by muse, mutect2, varscan2
- CCT5 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54723509; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 22/104 reads (21%) | catalogued as rs762194001; called by mutect2, varscan2
- CEBPG | c.374A>G p.H125R | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs1460777331, COSV52288010; called by muse, mutect2, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 46/155 reads (30%) | catalogued as rs375852685; called by mutect2, varscan2
- CEP120 | c.2213del p.K738Rfs*29 | Frame Shift Del (DEL) | VAF 90/343 reads (26%) | catalogued as COSV100071584; called by mutect2, pindel, varscan2
- CFAP61 | c.2548G>A p.V850M | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV55618817; called by muse, mutect2, varscan2
- CGN | c.2905-1G>A p.X969_splice | Splice Site (SNP) | VAF 13/52 reads (25%) | catalogued as COSV54973162; called by muse, mutect2, varscan2
- CHD8 | c.1679C>T p.A560V (on ENST00000646647 / NM_001170629.2; = p.A281V on NM_020920.4) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs769523871, COSV67872454; called by muse, mutect2, varscan2
- CHL1 | c.1519G>A p.A507T (on ENST00000397491 / NM_001253387.1; = p.A523T on NM_006614.4) | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as COSV56604520; called by muse, mutect2, varscan2
- CKAP2 | c.1817dup p.V607Gfs*4 (on ENST00000378037 / NM_001098525.2; = p.V606Gfs*4 on NM_018204.5) | Frame Shift Ins (INS) | VAF 33/154 reads (21%) | catalogued as rs752250702; called by mutect2, varscan2
- CKM | c.815T>C p.M272T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs781018931, COSV53468323; called by muse, mutect2, varscan2
- CLEC17A | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as rs1441236364, COSV60428417; called by muse, mutect2, varscan2
- CLPB | c.162del p.R55Afs*186 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs756188595; called by mutect2, varscan2
- CLUL1 | c.41G>T p.W14L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV58112079, COSV58113255; called by muse, mutect2, varscan2
- CNNM2 | c.1754C>T p.T585I | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV64001774; called by muse, mutect2, varscan2
- COL5A2 | c.916G>T p.G306C | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66414336; called by muse, mutect2, varscan2
- CPT1C | c.1360T>C p.F454L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as COSV54921812; called by muse, mutect2, varscan2
- CSDE1 | c.1710A>C p.K570N (on ENST00000358528 / NM_001007553.3; = p.K539N on NM_007158.6) | Missense Mutation (SNP) | VAF 117/488 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.463); catalogued as COSV54758129; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 38/210 reads (18%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSMD3 | c.5173T>C p.Y1725H (on ENST00000297405 / NM_001363185.1; = p.Y1621H on NM_052900.3) | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV52299080; called by muse, mutect2, varscan2
- CTNND2 | c.3000-2A>G p.X1000_splice | Splice Site (SNP) | VAF 20/87 reads (23%) | catalogued as COSV58922103; called by muse, mutect2, varscan2
- CTR9 | c.2399G>A p.G800E | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.366); catalogued as rs1185381021, COSV63729511; called by muse, mutect2
- CTSA | c.990del p.C331Afs*36 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs758642867; called by mutect2, pindel, varscan2
- CUX1 | c.1289del p.P430Lfs*27 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs782381199; called by mutect2, pindel, varscan2
- CYB5RL | c.247A>G p.I83V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV55279112; called by muse, mutect2, varscan2
- CYFIP2 | c.2572G>A p.A858T (on ENST00000616178 / NM_001291722.2; = p.A833T on NM_014376.4) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs377031549, COSV56635928; called by muse, mutect2, varscan2
- DBH | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs370254562; called by muse, mutect2, varscan2
- DCHS1 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV55034262, COSV55039579; called by muse, mutect2, varscan2
- DDI2 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 13/294 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1300606561, COSV60781306; called by muse, mutect2
- DENND5A | c.3242C>T p.P1081L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769645688, COSV60232686; called by muse, mutect2, varscan2
- DGKK | c.2937G>A p.M979I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as COSV65709248; called by muse, mutect2, varscan2
- DHX57 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 112/423 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs370897825; called by muse, mutect2, varscan2
- DIDO1 | c.4333C>T p.P1445S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV56633011; called by muse, mutect2
- DLK1 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs755998526, COSV57992425; called by muse, mutect2, varscan2
- DMTF1 | c.1853A>G p.H618R | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV57539242; called by muse, mutect2, varscan2
- DMXL1 | c.8609C>G p.T2870S | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1283525013, COSV100222953, COSV60719838; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs745893364; called by mutect2, varscan2
- DNER | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as rs1196138483, COSV59174898; called by muse, mutect2, varscan2
- DOCK10 | c.1122del p.D375Ifs*8 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs750262341; called by mutect2, varscan2
- DPP3 | c.1392C>T p.D464= | Splice Region (SNP) | VAF 13/48 reads (27%) | catalogued as rs560168052, COSV64757887; called by muse, mutect2, varscan2
- DYNC1H1 | c.483del p.F161Lfs*52 | Frame Shift Del (DEL) | VAF 52/202 reads (26%) | catalogued as rs1566996283; called by mutect2, pindel, varscan2
- EAF2 | c.326T>A p.V109E | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99877309; called by mutect2, varscan2
- EEFSEC | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.08); catalogued as rs530813952, COSV54631945; called by muse, mutect2, varscan2
- EGFL6 | c.1567G>T p.E523* | Nonsense Mutation (SNP) | VAF 59/243 reads (24%) | catalogued as COSV63633480, COSV63635058; called by muse, mutect2, varscan2
- EML3 | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV53874479; called by muse, mutect2, varscan2
- ENOX1 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs746354728, COSV54912550; called by muse, mutect2, varscan2
- FAM135B | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 62/357 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.058); catalogued as COSV52749836; called by muse, mutect2, varscan2
- FAM151A | c.351del p.T118Lfs*43 | Frame Shift Del (DEL) | VAF 38/190 reads (20%) | catalogued as rs749953492; called by mutect2, varscan2
- FAM160A2 | c.2602G>A p.A868T (on ENST00000449352 / NM_001098794.2; = p.A882T on NM_032127.4) | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56414306; called by muse, mutect2, varscan2
- FAM222B | c.181del p.I61Sfs*6 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as COSV100368253; called by mutect2, pindel, varscan2
- FAM71A | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV54237017; called by muse, mutect2, varscan2
- FAT1 | c.10906C>T p.Q3636* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV71675733; called by muse, mutect2, varscan2
- FAT3 | c.10999C>T p.H3667Y | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs775806768, COSV53165451; called by muse, mutect2, varscan2
- FAT4 | c.10644T>A p.Y3548* | Nonsense Mutation (SNP) | VAF 66/269 reads (25%) | catalogued as COSV58705286; called by muse, mutect2, varscan2
- FLOT2 | c.818A>G p.Q273R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV67529450; called by muse, mutect2, varscan2
- FMOD | c.929del p.P310Qfs*31 | Frame Shift Del (DEL) | VAF 50/184 reads (27%) | catalogued as COSV61610636; called by mutect2, pindel, varscan2
- FOCAD | c.2726T>C p.L909P | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.694); catalogued as COSV58106706; called by muse, mutect2, varscan2
- FOXO1 | c.1763G>A p.G588D | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs751994432, COSV65428374; called by muse, mutect2, varscan2
- FOXO1 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs994659376, COSV65428337; called by muse, mutect2
- FRMD8 | c.941G>A p.G314D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV58213970; called by muse, mutect2, varscan2
- GAB2 | c.1693C>T p.R565C (on ENST00000361507 / NM_080491.3; = p.R527C on NM_012296.3) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs1191816879, COSV60870186; called by muse, mutect2, varscan2
- GBA | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0.011); catalogued as COSV59170888; called by muse, mutect2, varscan2
- GCM2 | c.1169C>A p.S390Y | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV65276422; called by muse, mutect2, varscan2
- GOT1L1 | c.870del p.N291Tfs*24 | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | catalogued as rs768946390; called by mutect2, pindel, varscan2
- GPATCH8 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV71284452; called by muse, mutect2, varscan2
- GPCPD1 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as rs748581132, COSV66831688; called by muse, mutect2
- GSTA2 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 138/506 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV72415456; called by muse, mutect2, varscan2
- HAP1 | c.1835T>C p.L612P (on ENST00000310778 / NM_001367460.1; = p.L560P on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV57880545; called by muse, mutect2, varscan2
- HEATR6 | c.1311del p.V438Ffs*24 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs748699945, COSV51743560; called by mutect2, varscan2
- HEBP2 | c.593dup p.N198Kfs*2 | Frame Shift Ins (INS) | VAF 38/187 reads (20%) | catalogued as rs769528102; called by mutect2, varscan2
- IL6ST | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs535616300, COSV61142752; called by muse, mutect2, varscan2
- ISM1 | c.579del p.R194Gfs*82 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as rs762230866, COSV99339624; called by mutect2, pindel, varscan2
- JMY | c.2339T>C p.L780P | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs992430251, COSV68662203; called by muse, mutect2, varscan2
- KCNK17 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs376249168, COSV64686305; called by muse, mutect2, varscan2
- KIAA1217 | c.463del p.D155Mfs*19 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs1264299382; called by mutect2, pindel, varscan2
- KIF16B | c.2246del p.K749Rfs*3 | Frame Shift Del (DEL) | VAF 119/541 reads (22%) | catalogued as rs35229389; called by pindel, varscan2
- KIF4A | c.1566G>A p.M522I | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as COSV65545484; called by muse, mutect2
- KIRREL1 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs535287082, COSV63290786; called by muse, mutect2, varscan2
- KIRREL3 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs771036286, COSV69385975; called by muse, mutect2, varscan2
- KLF3 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54711262; called by muse, mutect2, varscan2
- KMT2A | c.6224G>A p.R2075H | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.08); catalogued as rs1555045451, COSV63287331; called by muse, mutect2, varscan2
- KMT2B | c.5179G>A p.A1727T | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV55868109; called by muse, mutect2
- KSR1 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs747753098, COSV52038382, COSV99259555; called by muse, mutect2, varscan2
- LAMA4 | c.5325A>G p.P1775= (on ENST00000230538 / NM_001105206.3; = p.P1768= on NM_002290.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 76/316 reads (24%) | catalogued as COSV57893567; called by muse, mutect2, varscan2
- LIFR | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs745909245, COSV54698400; called by muse, mutect2, varscan2
- LMX1A | c.661T>C p.C221R | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54227104; called by muse, mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 58/201 reads (29%) | catalogued as rs748712732; called by mutect2, varscan2
- LRRC41 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.682); catalogued as rs145805978; called by muse, mutect2, varscan2
- LRRC6 | c.809A>G p.K270R | Missense Mutation (SNP) | VAF 61/308 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.09); catalogued as COSV51546997; called by muse, mutect2, varscan2
- LTBP1 | c.4834+2T>C p.X1612_splice (on ENST00000404816 / NM_206943.4; = p.X1286_splice on NM_000627.4) | Splice Site (SNP) | VAF 41/195 reads (21%) | catalogued as COSV55384709; called by muse, mutect2, varscan2
- MARCHF7 | c.886del p.S296Hfs*9 | Frame Shift Del (DEL) | VAF 26/116 reads (22%) | catalogued as rs1383130845; called by mutect2, varscan2
- MARVELD2 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752821193, COSV57782176; called by muse, varscan2
- MAST1 | c.4324C>T p.R1442W | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); catalogued as COSV52245082; called by muse, mutect2
- MBD1 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV53998314, COSV54006473; called by muse, mutect2, varscan2
- MCM7 | c.1644del p.S549Pfs*8 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as COSV100384600, COSV57996372; called by mutect2, pindel
- MDM1 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV57448650; called by muse, mutect2, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 64/234 reads (27%) | catalogued as rs750307488; called by mutect2, varscan2
- MMP16 | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as rs1306557973, COSV54186061, COSV54193482; called by muse, mutect2, varscan2
- MOCS1 | c.1132C>T p.R378W | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs149586823, COSV51418796; called by muse, mutect2, varscan2
- MTCL1 | c.1828G>A p.G610S (on ENST00000306329 / NM_001378206.1; = p.G250S on NM_015210.4) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.096); catalogued as COSV60411091; called by muse, mutect2, varscan2
- MTMR9 | c.584del p.N195Mfs*4 | Frame Shift Del (DEL) | VAF 70/272 reads (26%) | catalogued as rs767880823; called by mutect2, varscan2
- MUC16 | c.39908C>T p.P13303L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated, low confidence (0.95); PolyPhen probably damaging (0.969); catalogued as rs369806025; called by muse, mutect2, varscan2
- MUC16 | c.18656A>T p.N6219I | Missense Mutation (SNP) | VAF 127/522 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); catalogued as COSV67488952, COSV67489365; called by muse, mutect2, varscan2
- MUC5B | c.8413T>C p.S2805P | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV71594931; called by muse, mutect2, varscan2
- MYBPC1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV62257092; called by muse, mutect2, varscan2
- MYBPC1 | c.2737G>A p.V913I (on ENST00000550270 / NM_206820.2; = p.V920I on NM_002465.4) | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV62257097; called by muse, mutect2, varscan2
- MYH15 | c.40del p.W14Gfs*5 | Frame Shift Del (DEL) | VAF 40/150 reads (27%) | catalogued as rs752868848; called by pindel, varscan2
- MYO9B | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as rs1364884004, COSV68279309; called by muse, mutect2
- NDST2 | c.410T>C p.L137S | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55217491; called by muse, mutect2, varscan2
- NEURL4 | c.3535G>T p.D1179Y | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59753011; called by muse, mutect2, varscan2
- NKAP | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65056895; called by muse, mutect2, varscan2
- NKAP | c.733A>G p.R245G | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV65056899; called by muse, mutect2, varscan2
- NLN | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66767089; called by muse, mutect2
- NR0B1 | c.523T>A p.S175T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.492); catalogued as COSV66764708; called by muse, mutect2
- NR4A2 | c.325dup p.Q109Pfs*3 | Frame Shift Ins (INS) | VAF 13/48 reads (27%) | catalogued as rs774629025; called by mutect2, varscan2
- NRG1 | c.272del p.K91Sfs*24 | Frame Shift Del (DEL) | VAF 38/178 reads (21%) | catalogued as rs1167519601; called by mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 28/142 reads (20%) | catalogued as rs776154715; called by mutect2, varscan2
- NUP205 | c.2189del p.P730Lfs*55 | Frame Shift Del (DEL) | VAF 31/322 reads (10%) | catalogued as rs1297134052, COSV53657833; called by mutect2, pindel, varscan2
- OAS1 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 69/294 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766223435, COSV52538368; called by muse, mutect2, varscan2
- OR10G8 | c.869G>T p.R290M | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70909348; called by muse, mutect2, varscan2
- OR7G1 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 101/394 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs147939135, COSV53318572; called by muse, mutect2, varscan2
- OSBP | c.2328G>T p.K776N | Missense Mutation (SNP) | VAF 106/494 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.216); catalogued as COSV55665353; called by muse, mutect2, varscan2
- OSGEP | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs748651554, COSV52833640; called by muse, mutect2, varscan2
- PCDH11X | c.442A>G p.I148V | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.173); catalogued as rs769245146, COSV53440924, COSV53499295; called by muse, mutect2, varscan2
- PCDH15 | c.4726T>C p.S1576P (on ENST00000644397 / NM_001354429.2; = p.S1518P on NM_001142771.2) | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV64729945; called by muse, mutect2, varscan2
- PCDH15 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57382308; called by muse, mutect2, varscan2
- PCDHB8 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as rs61741192, COSV50809084; called by muse, mutect2, varscan2
- PDHB | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57057892; called by muse, mutect2, varscan2
- PDS5B | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1200647108, COSV59723417; called by muse, mutect2, varscan2
- PICALM | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs967543022, COSV62673708; called by muse, mutect2, varscan2
- PIK3R1 | c.1508G>A p.R503Q (on ENST00000521381 / NM_181523.3; = p.R233Q on NM_181504.4) | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs765178503, COSV57130875; called by muse, mutect2, varscan2
- PIKFYVE | c.1320+2T>C p.X440_splice | Splice Site (SNP) | VAF 36/140 reads (26%) | catalogued as COSV52248266; called by muse, mutect2, varscan2
- PLA2G2D | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs747028462, COSV64282084; called by muse, mutect2, varscan2
- PLIN3 | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.675); catalogued as COSV55735081, COSV55735907; called by muse, mutect2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs772701630; called by mutect2, varscan2
- PLPP1 | c.545T>C p.V182A | Missense Mutation (SNP) | VAF 80/323 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV53307573; called by muse, mutect2, varscan2
- PNPLA3 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs201682627; called by muse, mutect2, varscan2
- PPEF2 | c.142T>C p.F48L | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54425714; called by muse, mutect2, varscan2
- PQBP1 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54431647; called by muse, mutect2, varscan2
- PTCH2 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763426183, COSV64710639; called by muse, mutect2, varscan2
- PTEN | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 66/296 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV64292105, COSV64302293; called by muse, mutect2, varscan2
- PTGER4 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV56722353; called by muse, mutect2, varscan2
- PTMS | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs763082021, COSV52567619; called by muse, mutect2, varscan2
- PWP1 | c.778C>A p.L260I | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV69833447; called by muse, mutect2, varscan2
- RANBP10 | c.1320G>T p.Q440H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.191); catalogued as COSV58160727; called by muse, mutect2, varscan2
- RAPGEF4 | c.1929G>T p.K643N | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as COSV51412321; called by muse, mutect2, varscan2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 53/185 reads (29%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBM43 | c.213del p.V72Lfs*13 | Frame Shift Del (DEL) | VAF 34/148 reads (23%) | catalogued as rs746242773; called by mutect2, varscan2
- RELN | c.3098G>A p.C1033Y | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59030417; called by muse, mutect2, varscan2
- RET | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.018); catalogued as COSV60702479; called by muse, mutect2, varscan2
- RHPN2 | c.1806_1808del p.N602del | In Frame Del (DEL) | VAF 60/235 reads (26%) | catalogued as rs776067822; called by pindel, varscan2
- RHPN2 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs530284964, COSV54284155; called by muse, mutect2, varscan2
- RP1L1 | c.3233G>A p.R1078Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs750435765, COSV66759517; called by muse, mutect2, varscan2
- RPF2 | c.713T>C p.L238S | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV64370501; called by muse, mutect2
- RPL18A | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1346951328; called by muse, mutect2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 36/132 reads (27%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RSPRY1 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV68028499; called by muse, mutect2, varscan2
- RUFY2 | c.457del p.M153Wfs*8 | Frame Shift Del (DEL) | VAF 25/97 reads (26%) | catalogued as rs759904440; called by mutect2, varscan2
- RYR2 | c.14217del p.F4739Lfs*15 | Frame Shift Del (DEL) | VAF 18/87 reads (21%) | catalogued as rs749201569; called by mutect2, varscan2
- SCN2B | c.561del p.E188Sfs*4 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs1271094414; called by mutect2, pindel, varscan2
- SH3PXD2A | c.1798C>T p.R600W (on ENST00000369774 / NM_001365079.1; = p.R572W on NM_014631.2) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs772194389, COSV60116143; called by muse, mutect2, varscan2
- SHISA3 | c.340T>C p.S114P | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100069894, COSV59980480; called by muse, mutect2, varscan2
- SIGLEC9 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV51587729; called by muse, mutect2
- SIN3A | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV64584735; called by muse, varscan2
- SLC12A1 | c.2628del p.D877Mfs*46 | Frame Shift Del (DEL) | VAF 33/161 reads (20%) | catalogued as rs1419151341, COSV66797187; called by mutect2, pindel, varscan2
- SLC25A16 | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV56266091; called by muse, mutect2, varscan2
- SLC2A7 | c.1278G>A p.W426* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | catalogued as COSV68902325; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 24/100 reads (24%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC4A7 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.908); catalogued as rs779940746, COSV55400758; called by muse, mutect2, varscan2
- SLC5A10 | c.1171C>A p.L391I (on ENST00000395645 / NM_001042450.4; = p.L407I on NM_152351.5) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.562); catalogued as COSV58761585; called by muse, mutect2, varscan2
- SLC7A2 | c.154G>T p.V52F (on ENST00000494857 / NM_001370338.1; = p.V92F on NM_003046.6) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50270490; called by muse, mutect2, varscan2
- SNAPC3 | c.920T>A p.F307Y | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.178); catalogued as COSV66402977; called by muse, mutect2, varscan2
- SPATA31A1 | c.2242G>A p.V748M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs1176921169; called by mutect2, varscan2
- SPICE1 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs141190252, COSV55620351, COSV55624417; called by muse, mutect2, varscan2
- SPTBN1 | c.6976G>A p.A2326T | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs200348448, COSV63344175; called by muse, mutect2, varscan2
- SREBF1 | c.227C>A p.P76H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV55419566; called by muse, mutect2
- STK24 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs376391138, COSV64823634; called by muse, mutect2, varscan2
- STYXL2 | c.2528T>C p.M843T | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV54808238; called by muse, mutect2, varscan2
- SVEP1 | c.7223G>A p.C2408Y | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52843305; called by muse, mutect2, varscan2
- SYT2 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs764945265, COSV66143053; called by muse, mutect2, varscan2
- TBC1D19 | c.326T>A p.L109* | Nonsense Mutation (SNP) | VAF 30/158 reads (19%) | catalogued as COSV53521043; called by muse, mutect2, varscan2
- TBC1D20 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.404); catalogued as rs1399755085, COSV62613091, COSV62613366; called by muse, mutect2, varscan2
- TENM4 | c.6848G>A p.R2283Q | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs778832577, COSV53664437; called by muse, mutect2, varscan2
- TG | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.163); catalogued as rs142432006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMC7 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58587282; called by muse, mutect2, varscan2
- TMOD3 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746856695, COSV57942596; called by muse, mutect2, varscan2
- TOE1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs749051888, COSV59156934; called by muse, mutect2, varscan2
- TOPBP1 | c.361del p.R121Gfs*10 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | catalogued as COSV53434676; called by mutect2, pindel
- TPTE | c.956C>G p.T319S (on ENST00000618007 / NM_199261.4; = p.T301S on NM_199259.4) | Missense Mutation (SNP) | VAF 76/959 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.03); catalogued as rs538136276; called by muse, mutect2
- TRIM26 | c.845del p.K282Rfs*16 | Frame Shift Del (DEL) | VAF 66/134 reads (49%) | catalogued as rs1271434984; called by mutect2, varscan2
- TRIM33 | c.1172G>T p.R391I | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as COSV61825547; called by muse, mutect2, varscan2
- TRMT11 | c.923A>T p.D308V | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57674148; called by muse, mutect2, varscan2
- TRRAP | c.2282G>T p.R761L | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62853068; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 32/137 reads (23%) | catalogued as rs760251146; called by mutect2, varscan2
- TXNL1 | c.514A>G p.N172D | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV54180848; called by muse, mutect2
- TXNRD2 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1044687486, COSV57634678; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | catalogued as rs767420916; called by mutect2, varscan2
- URGCP | c.1763C>T p.T588M (on ENST00000453200 / NM_001077663.3; = p.T579M on NM_017920.4) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs537964326, COSV56245139; called by muse, mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs764735138; called by mutect2, varscan2
- USP9X | c.4748A>G p.N1583S | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.026); catalogued as COSV61074443; called by muse, mutect2, varscan2
- UVRAG | c.709del p.S237Vfs*6 | Frame Shift Del (DEL) | VAF 30/124 reads (24%) | catalogued as rs762976381; called by mutect2, varscan2
- VPS26B | c.506A>G p.E169G | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55546416; called by muse, mutect2, varscan2
- WRAP53 | c.1565del p.A522Gfs*26 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs373064567, COSV56832921, COSV56833408; called by pindel, varscan2
- XRCC4 | c.138A>G p.T46= | Splice Region (SNP) | VAF 39/154 reads (25%) | catalogued as COSV56544376; called by muse, mutect2, varscan2
- XRN1 | c.703del p.T235Hfs*19 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | catalogued as rs779316292; called by mutect2, pindel, varscan2
- ZBED9 | c.854A>T p.E285V | Missense Mutation (SNP) | VAF 62/232 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV71729741; called by muse, mutect2, varscan2
- ZFX | c.1778C>T p.T593M | Missense Mutation (SNP) | VAF 79/322 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770714295, COSV58449692; called by muse, mutect2, varscan2
- ZFYVE26 | c.4222A>G p.I1408V | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61332988; called by muse, mutect2, varscan2
- ZNF142 | c.86dup p.P30Afs*4 | Frame Shift Ins (INS) | VAF 5/33 reads (15%) | catalogued as rs750522983; called by mutect2, pindel
- ZNF195 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 39/312 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.238); catalogued as rs778995294, COSV50002054; called by muse, mutect2, varscan2
- ZNF3 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs1409993961, COSV52796431; called by muse, mutect2, varscan2
- ZNF318 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 37/176 reads (21%) | catalogued as rs866272609, COSV58929874; called by muse, mutect2, varscan2
- ZNF557 | c.799C>T p.R267C (on ENST00000414706 / NM_001044388.2; = p.R274C on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs190142455, COSV53275298, COSV99422310; called by muse, mutect2, varscan2
- ZNF594 | c.1350C>A p.H450Q | Missense Mutation (SNP) | VAF 83/359 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV68386106; called by muse, mutect2, varscan2
- ZNF699 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV58026781; called by muse, mutect2, varscan2
- ZNF786 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as rs372708682; called by muse, varscan2
- ZNF804B | c.3736A>G p.I1246V | Missense Mutation (SNP) | VAF 64/309 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs768244132, COSV60850937; called by muse, mutect2, varscan2
- ZRANB2 | c.901del p.R301Dfs*38 (on ENST00000370920 / NM_203350.3; = p.R301Dfs*12 on NM_005455.5) | Frame Shift Del (DEL) | VAF 49/236 reads (21%) | catalogued as COSV54672452; called by mutect2, pindel, varscan2
- ZSCAN21 | c.653A>T p.E218V | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV52852252; called by muse, mutect2, varscan2
- ABI3BP | c.1832dup p.S612Kfs*3 | Frame Shift Ins (INS) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- ARID1A | c.3281del p.K1094Sfs*67 | Frame Shift Del (DEL) | VAF 35/158 reads (22%) | called by mutect2, pindel, varscan2
- ARID5B | c.1535_1545del p.V512Efs*12 | Frame Shift Del (DEL) | VAF 56/241 reads (23%) | called by mutect2, pindel, varscan2
- B3GNT5 | c.36del p.K12Nfs*4 | Frame Shift Del (DEL) | VAF 78/285 reads (27%) | called by mutect2, pindel, varscan2
- BTG3 | c.575del p.K192Sfs*37 | Frame Shift Del (DEL) | VAF 27/154 reads (18%) | called by mutect2, pindel, varscan2
- CCDC151 | c.267del p.F89Lfs*27 | Frame Shift Del (DEL) | VAF 31/137 reads (23%) | called by mutect2, pindel, varscan2
- CCDC83 | c.168del p.K56Nfs*9 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | called by mutect2, pindel, varscan2
- CCDC90B | c.394del p.S132Vfs*6 | Frame Shift Del (DEL) | VAF 23/113 reads (20%) | called by mutect2, pindel, varscan2
- CDH11 | c.625del p.S209Rfs*27 | Frame Shift Del (DEL) | VAF 35/196 reads (18%) | called by mutect2, pindel, varscan2
- CELSR1 | c.4805del p.G1602Vfs*104 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel
- DZIP3 | c.936del p.K312Nfs*3 | Frame Shift Del (DEL) | VAF 69/375 reads (18%) | called by pindel, varscan2
- EPB41L1 | c.196_198del p.K66del | In Frame Del (DEL) | VAF 25/84 reads (30%) | called by mutect2, pindel, varscan2
- EPHA5 | c.242del p.N81Mfs*24 | Frame Shift Del (DEL) | VAF 30/146 reads (21%) | called by mutect2, pindel, varscan2
- EXOC1 | c.2259del p.E754Kfs*18 | Frame Shift Del (DEL) | VAF 42/131 reads (32%) | called by mutect2, varscan2
- FAM135B | c.3312del p.E1105Nfs*2 | Frame Shift Del (DEL) | VAF 32/156 reads (21%) | called by mutect2, pindel, varscan2
- FAM151B | c.452del p.L151* | Frame Shift Del (DEL) | VAF 24/107 reads (22%) | called by mutect2, pindel, varscan2
- FXR2 | c.1619del p.P540Qfs*32 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, varscan2
- GANC | c.1002del p.L335Cfs*2 | Frame Shift Del (DEL) | VAF 70/265 reads (26%) | called by mutect2, pindel, varscan2
- GDI1 | c.188del p.P63Lfs*14 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- H3C2 | c.134dup p.T46Hfs*53 | Frame Shift Ins (INS) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- ILF3 | c.1201del p.Q401Rfs*3 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by pindel, varscan2
- ITGA2B | c.1958del p.P653Rfs*3 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 58/146 reads (40%) | called by mutect2, varscan2
- KDM5C | c.3642_3643del p.V1216Afs*83 | Frame Shift Del (DEL) | VAF 12/96 reads (13%) | called by pindel, varscan2
- MACF1 | c.19677del p.K6559Nfs*2 (on ENST00000372915; = p.K4604Nfs*2 on NM_012090.5) | Frame Shift Del (DEL) | VAF 59/251 reads (24%) | called by mutect2, pindel, varscan2
- MARVELD2 | c.149del p.P50Lfs*22 | Frame Shift Del (DEL) | VAF 26/134 reads (19%) | called by pindel, varscan2
- NCAN | c.2395del p.L799Wfs*28 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- NFE2L1 | c.2159_2161del p.E720del | In Frame Del (DEL) | VAF 16/61 reads (26%) | called by pindel, varscan2
- NOL6 | c.2857del p.Q953Kfs*32 | Frame Shift Del (DEL) | VAF 13/80 reads (16%) | called by mutect2, varscan2
- NPL | c.677dup p.T227Dfs*9 | Frame Shift Ins (INS) | VAF 24/96 reads (25%) | called by mutect2, varscan2
- NR3C2 | c.1804dup p.I602Nfs*8 | Frame Shift Ins (INS) | VAF 54/252 reads (21%) | called by mutect2, pindel, varscan2
- PHIP | c.4387del p.R1463Gfs*3 | Frame Shift Del (DEL) | VAF 53/508 reads (10%) | called by mutect2, pindel, varscan2
- PPFIA3 | c.2045del p.P682Lfs*46 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel
- PPP1R12C | c.1109_1110del p.G370Afs*8 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- RAE1 | c.1052del p.N351Ifs*12 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, varscan2
- REV3L | c.8874del p.G2959Efs*8 | Frame Shift Del (DEL) | VAF 23/122 reads (19%) | called by mutect2, pindel, varscan2
- RIT2 | c.480del p.F160Lfs*18 | Frame Shift Del (DEL) | VAF 24/114 reads (21%) | called by mutect2, pindel, varscan2
- RNF111 | c.687del p.E230Rfs*4 | Frame Shift Del (DEL) | VAF 96/398 reads (24%) | called by mutect2, pindel, varscan2
- RPE65 | c.815dup p.A273Sfs*8 | Frame Shift Ins (INS) | VAF 41/205 reads (20%) | called by mutect2, pindel, varscan2
- SERINC5 | c.207dup p.E70* | Frame Shift Ins (INS) | VAF 18/72 reads (25%) | called by mutect2, varscan2
- SI | c.1-3del | Splice Region (DEL) | VAF 23/131 reads (18%) | called by mutect2, pindel, varscan2
- SLC39A8 | c.1249_1251del p.D417del | In Frame Del (DEL) | VAF 36/170 reads (21%) | called by mutect2, pindel, varscan2
- TAF1 | c.2436del p.A813Pfs*14 (on ENST00000373790 / NM_138923.4; = p.A834Pfs*14 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 51/236 reads (22%) | called by mutect2, pindel, varscan2
- TCHHL1 | c.1483del p.A495Qfs*8 | Frame Shift Del (DEL) | VAF 125/615 reads (20%) | called by mutect2, pindel, varscan2
- TOP2A | c.3613del p.T1205Hfs*19 | Frame Shift Del (DEL) | VAF 20/124 reads (16%) | called by mutect2, pindel, varscan2
- TPR | c.2687del p.N896Mfs*9 | Frame Shift Del (DEL) | VAF 23/110 reads (21%) | called by mutect2, pindel, varscan2
- TUB | c.781del p.Q261Rfs*76 (on ENST00000299506 / NM_177972.3; = p.Q316Rfs*76 on NM_003320.4) | Frame Shift Del (DEL) | VAF 18/89 reads (20%) | called by mutect2, pindel, varscan2
- UGGT2 | c.3011dup p.R1005Qfs*24 | Frame Shift Ins (INS) | VAF 22/107 reads (21%) | called by mutect2, pindel, varscan2
- USP28 | c.2818del p.V940Sfs*5 | Frame Shift Del (DEL) | VAF 29/141 reads (21%) | called by mutect2, pindel, varscan2
- USP34 | c.5968dup p.I1990Nfs*30 | Frame Shift Ins (INS) | VAF 20/98 reads (20%) | called by mutect2, pindel, varscan2
- VPS13A | c.3690del p.F1230Lfs*7 | Frame Shift Del (DEL) | VAF 60/279 reads (22%) | called by mutect2, pindel, varscan2
- ZNF106 | c.174del p.G59Efs*16 | Frame Shift Del (DEL) | VAF 25/102 reads (25%) | called by mutect2, pindel, varscan2
- ZNF687 | c.2197del p.H733Mfs*30 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- ABCA13 | c.12135C>T p.A4045= | Silent (SNP) | VAF 53/205 reads (26%) | catalogued as rs756550869, COSV71293444; called by muse, mutect2, varscan2
- ABCA4 | c.4662A>G p.E1554= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV64672797; called by muse, mutect2, varscan2
- ACAD11 | c.2034C>T p.R678= | Silent (SNP) | VAF 40/136 reads (29%) | catalogued as COSV53900762; called by muse, mutect2, varscan2
- ADSS2 | c.1110G>A p.T370= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as rs139329929, COSV63696169; called by muse, mutect2, varscan2
- AKAP14 | c.75G>A p.P25= | Silent (SNP) | VAF 46/185 reads (25%) | catalogued as rs752908068, COSV57631169; called by muse, mutect2, varscan2
- AL035460.1 | c.225T>G p.L75= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV63028591; called by muse, mutect2, varscan2
- ALDOC | c.1074C>T p.Y358= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs1360823559, COSV52026276; called by muse, mutect2, varscan2
- ALG13 | c.729C>A p.L243= | Silent (SNP) | VAF 104/398 reads (26%) | catalogued as COSV52640967, COSV52644299; called by muse, mutect2, varscan2
- AMY2A | c.129T>C p.C43= | Silent (SNP) | VAF 90/389 reads (23%) | catalogued as COSV70214919; called by muse, mutect2, varscan2
- ARFGAP1 | c.708G>A p.A236= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs777510216, COSV62263916; called by muse, mutect2
- ARG2 | c.432C>A p.A144= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as COSV55777050; called by muse, mutect2, varscan2
- ATXN7 | c.2238C>T p.Y746= | Silent (SNP) | VAF 39/144 reads (27%) | catalogued as rs1399892964, COSV55755960; called by muse, mutect2, varscan2
- BCAS2 | c.663C>A p.I221= | Silent (SNP) | VAF 44/894 reads (5%) | catalogued as COSV65767777; called by muse, mutect2
- BMP1 | c.1008T>C p.P336= | Silent (SNP) | VAF 35/233 reads (15%) | catalogued as COSV60483295; called by muse, mutect2, varscan2
- BTBD3 | c.786C>T p.C262= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as rs55860534; called by muse, mutect2, varscan2
- C6orf201 | c.183G>A p.P61= | Silent (SNP) | VAF 45/196 reads (23%) | catalogued as rs147712155, COSV60988769; called by muse, mutect2, varscan2
- CAMK4 | c.1180C>T p.L394= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as COSV56681197; called by muse, mutect2, varscan2
- CASP7 | c.756C>T p.H252= | Silent (SNP) | VAF 36/156 reads (23%) | catalogued as rs754523047, COSV100614725; called by muse, mutect2
- CCDC85A | c.1497A>G p.S499= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV68155129; called by muse, mutect2, varscan2
- CCDC97 | c.657G>A p.P219= | Silent (SNP) | VAF 45/123 reads (37%) | catalogued as rs372944406, COSV54191643; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.447G>T p.A149= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV51593399; called by muse, mutect2, varscan2
- CFDP1 | c.669C>T p.G223= | Silent (SNP) | VAF 65/304 reads (21%) | catalogued as COSV52211557; called by muse, mutect2, varscan2
- CLDND1 | c.297A>G p.S99= | Silent (SNP) | VAF 37/123 reads (30%) | catalogued as COSV57859859; called by muse, mutect2, varscan2
- CLEC14A | c.501C>T p.N167= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs1339205878, COSV60561988; called by muse, mutect2, varscan2
- CLEC18B | c.411G>A p.A137= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs746285033, COSV60578678; called by muse, mutect2, varscan2
- CNTN3 | c.2796G>A p.E932= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV55182620; called by muse, mutect2, varscan2
- DHX33 | c.1932G>A p.T644= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs376607303, COSV56578909; called by muse, mutect2, varscan2
- DNAH7 | c.5043A>G p.S1681= | Silent (SNP) | VAF 36/140 reads (26%) | catalogued as COSV56782608, COSV56784097; called by muse, mutect2
- DSCAM | c.450G>A p.S150= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as rs771827647, COSV68627331; called by muse, mutect2, varscan2
- FAM47C | c.618G>A p.P206= | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as rs200547398, COSV63724314; called by muse, mutect2, varscan2
- FANCM | c.5811C>T p.C1937= | Silent (SNP) | VAF 51/220 reads (23%) | catalogued as COSV57505873; called by muse, mutect2, varscan2
- FBXO38 | c.2472G>A p.G824= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs765922663, COSV57031076; called by muse, mutect2, varscan2
- FHL5 | c.273G>A p.T91= | Silent (SNP) | VAF 7/119 reads (6%) | catalogued as rs973572111, COSV100459820, COSV58735839; called by muse, mutect2
- FLG | c.1776C>A p.S592= | Silent (SNP) | VAF 70/280 reads (25%) | catalogued as COSV64247748; called by muse, mutect2, varscan2
- FOXR2 | c.126T>C p.A42= | Silent (SNP) | VAF 45/159 reads (28%) | catalogued as COSV59259562; called by muse, mutect2, varscan2
- GABRP | c.351G>A p.V117= | Silent (SNP) | VAF 78/289 reads (27%) | catalogued as rs536367107, COSV54665410; called by muse, mutect2, varscan2
- GLI4 | c.6A>G p.A2= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV60682730; called by muse, mutect2, varscan2
- GTF2H4 | c.1149G>A p.L383= | Silent (SNP) | VAF 40/146 reads (27%) | catalogued as rs147784543; called by muse, mutect2, varscan2
- GZF1 | c.1740C>T p.C580= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as rs145353404; called by muse, mutect2, varscan2
- H2BC18 | c.114C>T p.Y38= | Silent (SNP) | VAF 71/286 reads (25%) | catalogued as rs587643369, COSV58944830; called by muse, mutect2, varscan2
- HAO2 | c.288C>A p.A96= | Silent (SNP) | VAF 36/158 reads (23%) | catalogued as COSV58041868; called by muse, mutect2, varscan2
- HECW1 | c.2166G>A p.V722= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV67838754; called by muse, mutect2, varscan2
- HERC2 | c.11409A>G p.T3803= | Silent (SNP) | VAF 52/221 reads (24%) | catalogued as COSV55346605; called by muse, mutect2, varscan2
- HGH1 | c.954G>A p.L318= | Silent (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2
- HMGB2 | c.582G>A p.E194= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs1160694947, COSV56633492; called by muse, mutect2, varscan2
- HPS4 | c.1455G>A p.T485= | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as rs756215705, COSV100404277, COSV61105266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HTT | c.8322C>T p.S2774= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1222267238, COSV61868268; called by muse, mutect2, varscan2
- IK | c.1185C>T p.D395= | Silent (SNP) | VAF 32/147 reads (22%) | catalogued as rs190024283; called by muse, mutect2, varscan2
- KCNH3 | c.390C>T p.H130= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV57792569; called by muse, mutect2, varscan2
- KHDRBS1 | c.930G>A p.R310= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as COSV56983530; called by muse, mutect2, varscan2
- KIF16B | c.2214T>C p.D738= | Silent (SNP) | VAF 148/578 reads (26%) | catalogued as rs1180314468, COSV61713204; called by muse, varscan2
- KIF2C | c.1722T>C p.Y574= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as COSV64765545; called by muse, mutect2, varscan2
- KMT2D | c.14748G>A p.P4916= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs769171629, COSV56467169; called by muse, mutect2, varscan2
- LCAT | c.1128C>T p.S376= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV50454902; called by muse, mutect2, varscan2
- LDLRAD2 | c.126C>T p.D42= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV60829452; called by muse, mutect2
- LMTK2 | c.3636C>T p.G1212= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs576536697, COSV52002934; called by muse, mutect2, varscan2
- LRRC66 | c.1623T>C p.T541= | Silent (SNP) | VAF 67/288 reads (23%) | catalogued as COSV58636513; called by muse, mutect2, varscan2
- LRRC8D | c.1482G>A p.V494= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV61580957; called by muse, mutect2, varscan2
- LRRK1 | c.879C>T p.L293= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV52624754; called by muse, mutect2, varscan2
- MBOAT7 | c.219C>A p.A73= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV55477414; called by muse, mutect2, varscan2
- MEFV | c.2103G>A p.A701= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as rs104895095, COSV54818684; ClinVar: benign / not provided; called by muse, mutect2, varscan2
- MMP15 | c.660C>A p.A220= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV54681330; called by muse, mutect2, varscan2
- MNT | c.1371C>T p.H457= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs1206472893, COSV51513798; called by muse, mutect2, varscan2
- MYH15 | c.207A>G p.K69= | Silent (SNP) | VAF 90/358 reads (25%) | catalogued as COSV56318420; called by muse, varscan2
- MYO5B | c.1185G>A p.Q395= | Silent (SNP) | VAF 74/284 reads (26%) | catalogued as rs765441720, COSV53229170; called by muse, mutect2, varscan2
- NLRP12 | c.828C>T p.S276= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs1467922706, COSV60753804; called by muse, mutect2, varscan2
- NRDC | c.3624A>G p.T1208= | Silent (SNP) | VAF 59/281 reads (21%) | catalogued as COSV61408072; called by muse, mutect2, varscan2
- NRROS | c.174C>T p.H58= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs369864683; called by muse, mutect2, varscan2
- OCA2 | c.1656C>T p.H552= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs777131634, COSV62356597; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2A5 | c.192C>T p.H64= | Silent (SNP) | VAF 82/378 reads (22%) | catalogued as COSV68739077; called by muse, mutect2, varscan2
- OR2F1 | c.228T>C p.S76= | Silent (SNP) | VAF 117/517 reads (23%) | catalogued as rs1312619725, COSV67331977; called by muse, mutect2, varscan2
- OSR2 | c.531C>T p.C177= | Silent (SNP) | VAF 43/239 reads (18%) | catalogued as rs778807175, COSV52558594; called by muse, mutect2, varscan2
- PCDH19 | c.648G>A p.P216= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs996601558, COSV55257202; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHA7 | c.360C>T p.D120= | Silent (SNP) | VAF 33/201 reads (16%) | catalogued as COSV65345702; called by muse, mutect2, varscan2
- PCDHGA11 | c.675C>T p.G225= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs1218675162, COSV53925687; called by muse, mutect2, varscan2
- PCLO | c.5955G>A p.Q1985= | Silent (SNP) | VAF 136/710 reads (19%) | catalogued as rs745459553, COSV61661552; called by muse, mutect2, varscan2
- PFAS | c.2856C>T p.L952= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs754223356, COSV58982991; called by muse, mutect2, varscan2
- PHEX | c.441G>A p.A147= | Silent (SNP) | VAF 113/563 reads (20%) | catalogued as rs770726332, COSV65075622; called by muse, mutect2, varscan2
- PHYKPL | c.942A>G p.P314= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV57425990; called by muse, mutect2, varscan2
- PM20D1 | c.864C>T p.S288= | Silent (SNP) | VAF 42/159 reads (26%) | catalogued as rs527489092, COSV65648865; called by muse, mutect2, varscan2
- PNMA1 | c.90T>C p.C30= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV54098350; called by muse, mutect2, varscan2
- PPARGC1B | c.1284G>A p.Q428= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV58526428; called by muse, mutect2
- PPP1R26 | c.936G>A p.T312= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs534583468, COSV63357184; called by muse, mutect2, varscan2
- PSMD5 | c.1509C>T p.A503= | Silent (SNP) | VAF 43/213 reads (20%) | catalogued as rs374798091; called by muse, mutect2, varscan2
- PYHIN1 | c.666A>G p.A222= | Silent (SNP) | VAF 29/118 reads (25%) | catalogued as COSV63723863; called by muse, mutect2, varscan2
- RAB11FIP2 | c.444C>T p.T148= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as rs188765663, COSV62924859; called by muse, mutect2, varscan2
- RNF113A | c.255C>T p.S85= | Silent (SNP) | VAF 59/255 reads (23%) | catalogued as COSV65097762; called by muse, mutect2, varscan2
- SALL4 | c.1131G>A p.A377= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs1000652774, COSV53849907; called by muse, mutect2, varscan2
- SCN1A | c.1089A>G p.T363= | Silent (SNP) | VAF 47/184 reads (26%) | catalogued as COSV57684856; called by muse, mutect2, varscan2
- SHOX | c.132G>A p.A44= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs1037369829, COSV61862176; called by muse, mutect2, varscan2
- SHROOM3 | c.2247G>A p.S749= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV56038245; called by muse, mutect2
- SPOCK1 | c.516C>T p.L172= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as rs374427870; called by muse, mutect2
- ST3GAL1 | c.807C>T p.T269= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as rs1441278139, COSV60613294; called by muse, mutect2, varscan2
- SULF1 | c.1140G>A p.V380= | Silent (SNP) | VAF 30/442 reads (7%) | catalogued as COSV52691438; called by muse, mutect2
- SV2B | c.201G>A p.A67= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs755565945, COSV57700686; called by muse, mutect2, varscan2
- TBC1D25 | c.789C>T p.R263= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs782537940, COSV65124576; called by muse, mutect2
- TG | c.1416T>C p.F472= | Silent (SNP) | VAF 53/240 reads (22%) | catalogued as rs1474625104, COSV55091987; called by muse, mutect2, varscan2
- TNXB | c.9825C>T p.R3275= (on ENST00000647633; = p.R3028= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs1378651176, COSV64487926; called by muse, mutect2, varscan2
- TTPAL | c.6C>T p.S2= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as rs1336544801, COSV52829683; called by muse, mutect2, varscan2
- TUBB6 | c.1296C>T p.D432= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs1379827700, COSV52317041; called by muse, mutect2
- USP33 | c.2016A>T p.G672= | Silent (SNP) | VAF 4/82 reads (5%) | catalogued as COSV62471228; called by muse, mutect2
- USP40 | c.3276C>T p.N1092= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs367756872; called by muse, mutect2
- WDFY2 | c.762G>A p.T254= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs763060000, COSV53292517; called by muse, mutect2, varscan2
- WDFY3 | c.10443G>A p.Q3481= | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as COSV55712376; called by muse, mutect2
- XPOT | c.2433C>T p.S811= | Silent (SNP) | VAF 45/203 reads (22%) | catalogued as rs749009245, COSV60344364; called by muse, mutect2, varscan2
- ZFHX4 | c.9000C>T p.G3000= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as rs1183735569, COSV50565031; called by muse, mutect2, varscan2
- ZFHX4 | c.10632T>C p.S3544= | Silent (SNP) | VAF 43/228 reads (19%) | catalogued as COSV51492280; called by muse, mutect2, varscan2
- ZFP82 | c.1281C>T p.C427= | Silent (SNP) | VAF 164/455 reads (36%) | catalogued as rs368863670; called by muse, mutect2, varscan2
- ZNF365 | c.246G>A p.P82= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV67925383, COSV67926483; called by muse, mutect2, varscan2
- ZNF69 | c.258C>A p.L86= (on ENST00000429654 / NM_001364730.1; = p.L72= on NM_021915.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/364 reads (4%) | catalogued as COSV60904573; called by muse, mutect2
- AL353804.7 | chrX:73851927 del A | 3'Flank (DEL) | VAF 32/152 reads (21%) | catalogued as rs760456851; called by mutect2, varscan2
- CLN5 | c.*93C>T | 3'UTR (SNP) | VAF 36/126 reads (29%) | catalogued as COSV62919282; called by muse, mutect2, varscan2
- CREM | c.891-382G>A | Intron (SNP) | VAF 22/87 reads (25%) | catalogued as COSV59768794; called by muse, mutect2, varscan2
- EIF2AK2 | c.*2G>T | 3'UTR (SNP) | VAF 37/152 reads (24%) | catalogued as COSV99240114, COSV99240325; called by muse, mutect2, varscan2
- GCNT2 | c.925+27347del | Intron (DEL) | VAF 78/332 reads (23%) | called by mutect2, pindel, varscan2
- KLHL4 | c.*2851G>A | 3'UTR (SNP) | VAF 46/201 reads (23%) | catalogued as COSV64147181; called by muse, mutect2, varscan2
- SGIP1 | c.99+999del | Intron (DEL) | VAF 14/52 reads (27%) | catalogued as rs745636084, COSV52764888; called by mutect2, varscan2
- SNORD116-17 | n.45C>T | RNA (SNP) | VAF 15/368 reads (4%) | called by muse, mutect2
- ZBTB37 | chr1:173866916 C>G | 5'Flank (SNP) | VAF 30/151 reads (20%) | called by muse, mutect2, varscan2
